Somatic mutation profile of tumor specimen TARGET-20-PATJYT-03A (aliquot TARGET-20-PATJYT-03A-01D) from TARGET case TARGET-20-PATJYT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,659 days).
Specimen TARGET-20-PATJYT-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b5e192a-5443-4d68-a3b7-f9357de27dc4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATJYT-14A (Bone Marrow Normal), aliquot TARGET-20-PATJYT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/164e7e6c-e06c-4d61-be71-b83718faa803

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 68/166 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 75/178 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
